Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4437, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4437-01A (Primary Tumor).

██████████

Diagnosis/diagnoses:

Gastrectomy preparation with tumor-free resection margins and with the inclusion of a moderately differentiated adenocarcinoma (intestinal type) of the esophagogastric junction with infiltration of the perimuscular fatty tissue and with three regional lymph node metastases (pT2b N1 3/29 ██████████)

Source: NCI Genomic Data Commons file cc555415-c4c3-47a1-81ec-2e49b6dd8cb4 (TCGA-CG-4437.A3D1DB57-1600-4B6E-97C8-6614F5FA9A08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).